Somatic mutation profile of tumor specimen TARGET-40-PANGRW-01A (aliquot TARGET-40-PANGRW-01A-02D) from TARGET case TARGET-40-PANGRW, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.7 years (6,088 days).
Specimen TARGET-40-PANGRW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b05371d-9f6f-4b8b-8dad-ab9d9e75ef8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANGRW-10A (Blood Derived Normal), aliquot TARGET-40-PANGRW-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a20017c-972a-4ba3-90a3-1dcae04b95e1

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 5'UTR 2, Silent 1, Intron 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOD1 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV66291603; called by mutect2, varscan2
- AGAP4 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs143658188; called by muse, mutect2
- KDR | c.3511G>A p.D1171N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs890866273, COSV55765427; called by muse, mutect2, varscan2
- PHLPP2 | c.3310G>A p.G1104R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV100673779; called by muse, mutect2, varscan2
- DOCK2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MYO5A | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR11H7 | c.406A>T p.M136L | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PCBP3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); called by muse, mutect2
- PREP | c.74A>T p.N25I (on ENST00000369110; = p.N91I on NM_002726.5) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TESC | c.77A>T p.E26V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by mutect2, varscan2
- ZBTB11 | c.3023T>C p.V1008A | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PHGDH | c.21G>T p.R7= | Silent (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- AC053481.3 | n.559C>G | RNA (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- FAM3D | c.-17C>G | 5'UTR (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571412 G>A | 3'Flank (SNP) | VAF 4/38 reads (11%) | catalogued as rs1251782455; called by mutect2, varscan2
- LRRC59 | c.105+45G>A | Intron (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- SLC10A2 | c.-11C>A | 5'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
